Somatic mutation profile of tumor specimen TARGET-10-PATKYI-09A (aliquot TARGET-10-PATKYI-09A-01D) from TARGET case TARGET-10-PATKYI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 20.8 years (7,614 days).
Specimen TARGET-10-PATKYI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a453b65-7ca4-410e-af29-afe87f039b7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATKYI-10A (Blood Derived Normal), aliquot TARGET-10-PATKYI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6207ff9-1340-4dfa-a401-8edd7921a7ba

The open-access MAF lists 41 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, Frame Shift Ins 5, Intron 4, Nonsense Mutation 3, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GALT4 | c.725dup p.R243Qfs*108 | Frame Shift Ins (INS) | VAF 11/28 reads (39%) | catalogued as rs779828300; called by mutect2, pindel, varscan2
- CAPRIN2 | c.1481C>G p.P494R | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV51836543; called by muse, mutect2, varscan2
- CAPRIN2 | c.584A>G p.Q195R | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51836557; called by muse, mutect2, varscan2
- COL12A1 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as COSV59390633; called by muse, mutect2, varscan2
- DHX15 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 36/65 reads (55%) | catalogued as COSV61029772; called by muse, mutect2, varscan2
- ENPEP | c.2530C>T p.L844F | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV54459431; called by muse, mutect2, varscan2
- EZH2 | c.1697G>C p.C566S (on ENST00000460911 / NM_001203247.2; = p.C571S on NM_004456.5) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as COSV57457962, COSV57465628; called by muse, mutect2
- HS6ST3 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1482738025, COSV65002329, COSV65019871; called by muse, mutect2, varscan2
- METTL22 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.833); catalogued as rs376519641, COSV50837337; called by muse, mutect2
- MUC2 | c.2695G>A p.V899I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.18); catalogued as rs760492950; called by muse, mutect2, varscan2
- MYO9A | c.5152C>T p.R1718* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as COSV61860946; called by muse, mutect2, varscan2
- NOC4L | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as COSV57960709; called by muse, mutect2, varscan2
- OR3A1 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs150533143; called by muse, mutect2, varscan2
- P2RX1 | c.58dup p.R20Pfs*7 | Frame Shift Ins (INS) | VAF 25/48 reads (52%) | catalogued as rs35715771; called by mutect2, pindel, varscan2
- PRKACG | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.113); catalogued as COSV55260985; called by muse, mutect2, varscan2
- ROBO2 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV59949192; called by muse, mutect2
- RYR2 | c.11848G>A p.V3950M | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63723123; called by muse, mutect2, varscan2
- SLC10A4 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201020849; called by muse, mutect2, varscan2
- SPATA18 | c.605G>C p.S202T | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV54652214; called by muse, mutect2, varscan2
- TAS2R16 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs28371571; called by muse, mutect2, varscan2
- ZNF420 | c.348A>C p.K116N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV58497075; called by muse, mutect2, varscan2
- DTX1 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NLRC5 | c.2767_2774dup p.C925* | Frame Shift Ins (INS) | VAF 7/26 reads (27%) | called by mutect2, varscan2
- NLRC5 | c.3027_3028insAGGCCCC p.D1010Rfs*12 | Frame Shift Ins (INS) | VAF 17/34 reads (50%) | called by mutect2, pindel, varscan2
- NOBOX | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NOTCH1 | c.7020dup p.S2341Lfs*13 | Frame Shift Ins (INS) | VAF 6/11 reads (55%) | called by mutect2, varscan2
- POTEA | c.174G>C p.R58S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CCND2 | c.381C>T p.T127= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs184590007; called by muse, mutect2, varscan2
- ITPR3 | c.4176G>A p.P1392= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs113295587; called by muse, mutect2, varscan2
- MRGPRG | c.753G>A p.S251= | Silent (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- NOA1 | c.1863C>T p.A621= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as rs770579795; called by muse, mutect2, varscan2
- NRROS | c.975C>T p.S325= | Silent (SNP) | VAF 24/136 reads (18%) | catalogued as rs369822583; called by muse, mutect2, varscan2
- OR8H1 | c.807G>A p.R269= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV57296391; called by muse, mutect2, varscan2
- SMIM33 | c.111T>C p.P37= | Silent (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- THSD7B | c.1335C>T p.S445= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs768714043; called by muse, mutect2, varscan2
- DZIP1 | c.2524+31G>A | Intron (SNP) | VAF 14/21 reads (67%) | catalogued as rs368056052; called by mutect2, varscan2
- HLA-F | c.65-65C>T | Intron (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2
- IGSF9B | c.*33G>T | 3'UTR (SNP) | VAF 4/8 reads (50%) | catalogued as rs1387357999; called by muse, mutect2, varscan2
- MUC21 | c.61+22C>A | Intron (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- PPP2R1B | c.115-425T>A | Intron (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
- PTPN7 | chr1:202160598 G>T | 5'Flank (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
